Somatic mutation profile of tumor specimen MMRF_2647_1_BM_CD138pos (aliquot MMRF_2647_1_BM_CD138pos_T1_KHS5U_L13414) from MMRF case MMRF_2647, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 57.2 years (20,880 days).
Specimen MMRF_2647_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 03a1e396-a18e-4eea-9a7a-271c9e08df9c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2647_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2647_1_PB_WBC_C2_KHS5U_L13415; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/df7f489c-0b78-4a09-965b-ebc4800ff25d

The open-access MAF lists 187 somatic variants for this specimen: 98 protein-altering or splice-affecting, 18 silent, 71 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 87, 3'UTR 47, Silent 18, Intron 13, 5'UTR 6, Nonsense Mutation 4, Splice Site 3, 3'Flank 2, 5'Flank 2, Splice Region 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC100868.1 | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 40/352 reads (11%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.017); catalogued as rs541260451; called by muse, varscan2
- ADGRV1 | c.5401G>A p.E1801K | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as COSV67989879; called by muse, mutect2, varscan2
- ANKRD36C | c.769C>T p.H257Y | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV71726949; called by muse, mutect2, varscan2
- ATAD2 | c.361C>T p.H121Y | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs765773035; called by muse, mutect2, varscan2
- BACH2 | c.1976C>T p.A659V | Missense Mutation (SNP) | VAF 33/168 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV57604644; called by muse, mutect2, varscan2
- BLVRA | c.704C>G p.S235C | Missense Mutation (SNP) | VAF 45/86 reads (52%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV104376726, COSV55513766; called by muse, mutect2, varscan2
- BMP7 | c.866G>A p.R289H | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as COSV67780806, COSV99060160; called by muse, mutect2
- CACNA1E | c.3977A>C p.E1326A | Missense Mutation (SNP) | VAF 62/147 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.369); catalogued as COSV62434986; called by muse, mutect2, varscan2
- CD248 | c.335C>T p.T112M | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1016367945; called by muse, mutect2
- CHRD | c.1814C>T p.S605L | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.312); catalogued as COSV52608986, COSV52610032; called by muse, mutect2
- COL4A3 | c.1187G>C p.W396S | Missense Mutation (SNP) | VAF 8/208 reads (4%) | SIFT tolerated (0.47); PolyPhen benign (0.049); catalogued as COSV67418782; called by muse, mutect2
- DSCAML1 | c.3406C>A p.P1136T (on ENST00000321322; = p.P1076T on NM_020693.4) | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1427760467, COSV58392360; called by muse, mutect2, varscan2
- EFR3B | c.1726G>A p.V576M | Missense Mutation (SNP) | VAF 75/133 reads (56%) | SIFT tolerated (0.73); PolyPhen benign (0.006); catalogued as rs1270589286, COSV53119525; called by muse, varscan2
- FBXW8 | c.1400C>T p.P467L (on ENST00000309909; = p.P505L on NM_012174.1) | Missense Mutation (SNP) | VAF 34/248 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.107); catalogued as rs1364784842; called by muse, mutect2, varscan2
- FLNC | c.982C>A p.P328T | Missense Mutation (SNP) | VAF 42/83 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as COSV57954981; called by muse, mutect2, varscan2
- FN1 | c.4891+4C>T | Splice Region (SNP) | VAF 28/207 reads (14%) | catalogued as rs750452839; called by muse, mutect2, varscan2
- GUCY1A1 | c.349A>C p.T117P | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.236); catalogued as rs142097871, COSV56657142; called by muse, mutect2, varscan2
- H2AC1 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 101/205 reads (49%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as rs772978548; called by muse, mutect2, varscan2
- HGF | c.1450G>A p.V484I | Missense Mutation (SNP) | VAF 42/73 reads (58%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as rs571102402, COSV55945679, COSV55950651; called by muse, mutect2, varscan2
- KCNH6 | c.1602G>C p.E534D | Missense Mutation (SNP) | VAF 67/290 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.038); catalogued as rs961770530; called by muse, mutect2, varscan2
- KCTD16 | c.1265T>G p.L422R | Missense Mutation (SNP) | VAF 54/111 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101568702, COSV72577033; called by muse, mutect2, varscan2
- KY | c.95A>G p.D32G | Missense Mutation (SNP) | VAF 97/221 reads (44%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.005); catalogued as rs754372668; called by muse, mutect2, varscan2
- LRRC7 | c.1525G>A p.E509K (on ENST00000651989 / NM_001370785.2; = p.E476K on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 141/290 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as rs1318855534, COSV50409067; called by muse, mutect2, varscan2
- MAL2 | c.460-1G>A p.X154_splice | Splice Site (SNP) | VAF 54/133 reads (41%) | catalogued as rs1563780427; called by muse, mutect2, varscan2
- MAX | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 16/90 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); catalogued as COSV52416961; called by muse, varscan2
- NDRG4 | c.940C>T p.R314C (on ENST00000570248 / NM_001378344.1; = p.R333C on NM_020465.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as rs745649023; called by muse, mutect2, varscan2
- PBX4 | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs199673541; called by muse, mutect2, varscan2
- PCSK9 | c.1207G>T p.E403* | Nonsense Mutation (SNP) | VAF 121/229 reads (53%) | catalogued as COSV56162829, COSV56164468; called by muse, mutect2, varscan2
- RBM24 | c.371C>T p.P124L (on ENST00000379052 / NM_001143942.2; = p.P79L on NM_153020.2) | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as rs1448844493, COSV59003260; called by muse, mutect2, varscan2
- RHBDF2 | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as COSV57422429; called by muse, mutect2
- RYR1 | c.4298A>G p.Y1433C | Missense Mutation (SNP) | VAF 23/168 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1331110158; called by muse, mutect2, varscan2
- SAFB | c.1433C>T p.S478F | Missense Mutation (SNP) | VAF 53/133 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.951); catalogued as COSV52654326, COSV99412729; called by muse, mutect2, varscan2
- SEC14L4 | c.174G>T p.R58S | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV55398510; called by muse, mutect2, varscan2
- SIPA1L2 | c.5099C>A p.S1700Y | Missense Mutation (SNP) | VAF 34/217 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53391910; called by muse, mutect2, varscan2
- SLC22A14 | c.1663C>T p.L555F | Missense Mutation (SNP) | VAF 41/259 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0.308); catalogued as rs749179440; called by muse, mutect2, varscan2
- TRANK1 | c.1996C>G p.L666V | Missense Mutation (SNP) | VAF 39/286 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.023); catalogued as rs759651847; called by muse, mutect2, varscan2
- TRIM46 | c.671G>A p.G224D | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.657); catalogued as COSV99826013; called by muse, mutect2
- ABTB1 | c.1167G>T p.K389N (on ENST00000232744 / NM_172027.3; = p.K247N on NM_032548.3) | Missense Mutation (SNP) | VAF 79/181 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- AGBL3 | c.1888C>A p.L630I | Missense Mutation (SNP) | VAF 23/209 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.366); called by muse, mutect2
- AL021546.1 | c.121G>T p.G41* | Nonsense Mutation (SNP) | VAF 18/375 reads (5%) | called by muse, mutect2
- C22orf42 | c.166A>C p.K56Q | Missense Mutation (SNP) | VAF 48/152 reads (32%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- C6 | c.1865C>A p.P622Q | Missense Mutation (SNP) | VAF 25/181 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- CCDC97 | c.812G>T p.W271L | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.766); called by muse, mutect2
- CD7 | c.274G>T p.G92W | Missense Mutation (SNP) | VAF 11/204 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COL1A1 | c.2154_2189del p.S720_G731del | In Frame Del (DEL) | VAF 92/240 reads (38%) | called by mutect2, pindel
- COL24A1 | c.3682-2A>C p.X1228_splice | Splice Site (SNP) | VAF 7/63 reads (11%) | called by muse, mutect2
- COL6A3 | c.2257G>T p.G753W | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSPG4 | c.4970T>C p.L1657P | Missense Mutation (SNP) | VAF 59/120 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- CYP4A22 | c.1395C>G p.N465K | Missense Mutation (SNP) | VAF 26/191 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- DNM3 | c.1196G>A p.R399K | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DRGX | c.575T>A p.F192Y | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- FAT4 | c.4397G>T p.G1466V | Missense Mutation (SNP) | VAF 141/253 reads (56%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FIGN | c.419C>G p.P140R | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FSCN2 | c.1005G>C p.E335D | Missense Mutation (SNP) | VAF 34/172 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GABRG3 | c.215T>C p.V72A | Missense Mutation (SNP) | VAF 28/207 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- HAL | c.950G>T p.C317F | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- HEXIM1 | c.602C>G p.A201G | Missense Mutation (SNP) | VAF 56/332 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HYDIN | c.9898G>A p.A3300T | Missense Mutation (SNP) | VAF 7/132 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.155); called by muse, mutect2
- IFNA6 | c.536G>C p.R179T | Missense Mutation (SNP) | VAF 95/252 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGHV3-72 | c.348C>G p.Y116* | Nonsense Mutation (SNP) | VAF 69/74 reads (93%) | called by muse, varscan2
- IRAK1 | c.1033A>C p.N345H | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- KLLN | c.144G>C p.R48S | Missense Mutation (SNP) | VAF 15/344 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.372); called by muse, mutect2
- LAMB3 | c.2527A>G p.N843D | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LILRA2 | c.331C>T p.P111S | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.445); called by muse, varscan2
- LONRF3 | c.716G>C p.G239A | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRP1 | c.9963C>G p.F3321L | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- LVRN | c.1979T>C p.V660A | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- MARK2 | c.679G>C p.D227H | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- MSR1 | c.1169G>T p.S390I | Missense Mutation (SNP) | VAF 16/235 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); called by muse, mutect2
- MUC16 | c.20162T>G p.L6721R | Missense Mutation (SNP) | VAF 7/156 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.651); called by muse, mutect2
- NACAD | c.1034G>T p.G345V | Missense Mutation (SNP) | VAF 36/206 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- NAV1 | c.4345G>T p.V1449F | Missense Mutation (SNP) | VAF 11/183 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); called by muse, mutect2
- NECAB2 | c.464A>T p.Y155F | Missense Mutation (SNP) | VAF 7/166 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); called by muse, mutect2
- OR10Z1 | c.56G>T p.S19I | Missense Mutation (SNP) | VAF 50/109 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- ORM2 | c.510_514del p.S171Cfs*10 | Frame Shift Del (DEL) | VAF 46/116 reads (40%) | called by mutect2, varscan2
- PDK4 | c.491T>G p.M164R | Missense Mutation (SNP) | VAF 54/100 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- PER2 | c.91G>C p.D31H | Missense Mutation (SNP) | VAF 33/185 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PHLDA1 | c.1066C>A p.P356T | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- PIK3C2B | c.38C>A p.S13Y | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- PITPNB | c.501G>C p.K167N | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- PPWD1 | c.401G>C p.G134A | Missense Mutation (SNP) | VAF 21/154 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- RACGAP1 | c.368C>T p.S123L | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- REC114 | c.119C>A p.P40Q | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- RSPH14 | c.921G>C p.K307N | Missense Mutation (SNP) | VAF 47/95 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- SHH | c.1286C>T p.T429I | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SLC25A48 | c.588C>A p.F196L (on ENST00000650267; = p.F142L on NM_001349335.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.011); called by muse, mutect2
- SLITRK2 | c.817C>T p.Q273* | Nonsense Mutation (SNP) | VAF 225/399 reads (56%) | called by muse, mutect2, varscan2
- SPTBN4 | c.1160T>G p.L387R | Missense Mutation (SNP) | VAF 58/148 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SWI5 | c.446T>C p.L149P | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- TCHP | c.960G>C p.Q320H | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- TFR2 | c.1420A>C p.I474L | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- TPO | c.2381G>A p.C794Y | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRPM2 | c.620C>T p.T207I | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTN | c.47101C>A p.P15701T (on ENST00000591111; = p.P8277T on NM_003319.4) | Missense Mutation (SNP) | VAF 53/159 reads (33%) | PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TUBAL3 | c.542C>G p.A181G | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TXNRD3 | c.1513T>G p.S505A | Missense Mutation (SNP) | VAF 99/212 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WNT7B | c.298+2T>A p.X100_splice | Splice Site (SNP) | VAF 12/126 reads (10%) | called by muse, mutect2
- ZSWIM5 | c.757C>A p.L253I | Missense Mutation (SNP) | VAF 34/341 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ABCA4 | c.3972G>A p.A1324= | Silent (SNP) | VAF 19/109 reads (17%) | catalogued as rs200965081; called by muse, mutect2, varscan2
- ACTN4 | c.141C>G p.A47= | Silent (SNP) | VAF 6/42 reads (14%) | called by muse, mutect2, varscan2
- APOBEC4 | c.615C>T p.V205= | Silent (SNP) | VAF 34/240 reads (14%) | called by muse, mutect2
- CASP8 | c.501C>T p.I167= (on ENST00000432109 / NM_033355.3; = p.I199= on NM_001228.4) | Silent (SNP) | VAF 12/266 reads (5%) | catalogued as COSV51849687; called by muse, mutect2
- CCNA1 | c.33T>C p.P11= | Silent (SNP) | VAF 10/74 reads (14%) | called by muse, mutect2, varscan2
- DISP2 | c.3652C>T p.L1218= | Silent (SNP) | VAF 20/146 reads (14%) | called by muse, mutect2, varscan2
- FAM155A | c.672G>T p.S224= | Silent (SNP) | VAF 107/113 reads (95%) | catalogued as rs1361251821; called by muse, mutect2, varscan2
- IGSF1 | c.174C>T p.C58= | Silent (SNP) | VAF 19/114 reads (17%) | catalogued as COSV100811942; called by muse, mutect2, varscan2
- KIF19 | c.543G>A p.V181= | Silent (SNP) | VAF 7/119 reads (6%) | called by muse, mutect2
- LCN15 | c.153C>A p.G51= | Silent (SNP) | VAF 47/310 reads (15%) | catalogued as COSV60209862; called by muse, mutect2, varscan2
- LRRC7 | c.2667G>A p.P889= (on ENST00000651989 / NM_001370785.2; = p.P856= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 58/137 reads (42%) | catalogued as rs759651343, COSV50411916; called by muse, mutect2, varscan2
- MALRD1 | c.147C>T p.D49= | Silent (SNP) | VAF 43/103 reads (42%) | called by muse, mutect2, varscan2
- SHISAL1 | c.270T>C p.G90= | Silent (SNP) | VAF 3/29 reads (10%) | catalogued as rs1359713450; called by muse, mutect2
- SLC26A9 | c.1467C>T p.S489= | Silent (SNP) | VAF 29/93 reads (31%) | catalogued as rs1360080754, COSV61606148; called by muse, mutect2, varscan2
- TAS1R3 | c.675C>A p.I225= | Silent (SNP) | VAF 69/139 reads (50%) | catalogued as rs761144545; called by muse, mutect2, varscan2
- UTP20 | c.5488C>T p.L1830= | Silent (SNP) | VAF 18/114 reads (16%) | called by muse, mutect2, varscan2
- ZEB2 | c.3399T>C p.D1133= | Silent (SNP) | VAF 52/479 reads (11%) | called by muse, mutect2, varscan2
- ZNF709 | c.1509C>G p.P503= | Silent (SNP) | VAF 19/299 reads (6%) | catalogued as COSV67195128; called by muse, mutect2
- AC024560.2 | n.783G>C | RNA (SNP) | VAF 17/159 reads (11%) | called by muse, mutect2, varscan2
- AC245748.1 | c.16-26607G>A | Intron (SNP) | VAF 6/66 reads (9%) | called by muse, mutect2
- ACSF3 | c.*804C>G | 3'UTR (SNP) | VAF 105/272 reads (39%) | called by muse, mutect2, varscan2
- ACTBL2 | c.*1396A>C | 3'UTR (SNP) | VAF 5/66 reads (8%) | called by muse, mutect2
- ATG16L2 | c.*77G>C | 3'UTR (SNP) | VAF 12/23 reads (52%) | called by muse, mutect2, varscan2
- ATG4A | c.*675C>G | 3'UTR (SNP) | VAF 25/29 reads (86%) | called by muse, mutect2, varscan2
- ATP1B1 | c.*64C>A | 3'UTR (SNP) | VAF 5/59 reads (8%) | called by muse, mutect2
- AVPR1B | c.*161A>G | 3'UTR (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2, varscan2
- C1orf21 | c.*8939A>G | 3'UTR (SNP) | VAF 12/117 reads (10%) | called by muse, mutect2, varscan2
- C20orf194 | c.*1655T>G | 3'UTR (SNP) | VAF 39/92 reads (42%) | called by muse, mutect2, varscan2
- CACNB2 | c.120+305del | Intron (DEL) | VAF 41/132 reads (31%) | called by mutect2, pindel, varscan2
- CACNB2 | c.213+109782C>T | Intron (SNP) | VAF 4/40 reads (10%) | called by muse, varscan2
- CALN1 | c.*7820A>C | 3'UTR (SNP) | VAF 14/147 reads (10%) | called by muse, mutect2
- CCDC170 | c.*2176C>T | 3'UTR (SNP) | VAF 5/59 reads (8%) | catalogued as rs909510438; called by muse, mutect2
- CGREF1 | chr2:27099328 G>A | 3'Flank (SNP) | VAF 9/144 reads (6%) | called by muse, mutect2
- COPZ1 | c.169+36G>T | Intron (SNP) | VAF 51/103 reads (50%) | called by muse, mutect2, varscan2
- DLX3 | c.*125C>G | 3'UTR (SNP) | VAF 31/71 reads (44%) | called by muse, mutect2, varscan2
- DNAJC5 | c.*3037G>T | 3'UTR (SNP) | VAF 76/148 reads (51%) | called by muse, mutect2, varscan2
- DTX3L | c.*2224G>T | 3'UTR (SNP) | VAF 13/20 reads (65%) | called by muse, mutect2, varscan2
- ELFN2 | c.*3825A>T | 3'UTR (SNP) | VAF 11/232 reads (5%) | called by muse, mutect2
- ERLIN2 | c.424+1546C>G | Intron (SNP) | VAF 14/77 reads (18%) | called by muse, mutect2, varscan2
- EVX1 | c.*1032T>C | 3'UTR (SNP) | VAF 46/115 reads (40%) | called by muse, mutect2, varscan2
- FAM53C | c.*1040G>C | 3'UTR (SNP) | VAF 6/144 reads (4%) | called by muse, mutect2
- FPGT-TNNI3K | c.2114+4180T>C | Intron (SNP) | VAF 19/134 reads (14%) | called by muse, mutect2, varscan2
- GABRG3 | c.*271A>T | 3'UTR (SNP) | VAF 5/77 reads (6%) | called by muse, mutect2
- GSTCD | c.1356+52T>C | Intron (SNP) | VAF 12/191 reads (6%) | called by muse, mutect2
- H2AC11 | c.*570C>T | 3'UTR (SNP) | VAF 124/261 reads (48%) | called by muse, varscan2
- HDAC11 | c.*1553T>G | 3'UTR (SNP) | VAF 9/254 reads (4%) | called by muse, mutect2
- HOGA1 | c.-145G>T | 5'UTR (SNP) | VAF 22/151 reads (15%) | called by muse, mutect2, varscan2
- HOXB2 | c.*19_*54del | 3'UTR (DEL) | VAF 35/299 reads (12%) | called by mutect2, pindel
- ITGA9 | c.*2729_*2755del | 3'UTR (DEL) | VAF 27/107 reads (25%) | called by mutect2, pindel, varscan2
- IVNS1ABP | c.766-21A>C | Intron (SNP) | VAF 82/196 reads (42%) | called by muse, mutect2, varscan2
- LIN7C | c.*2362G>C | 3'UTR (SNP) | VAF 9/144 reads (6%) | called by muse, mutect2
- MGAT3 | c.*2047C>T | 3'UTR (SNP) | VAF 15/136 reads (11%) | called by muse, mutect2, varscan2
- MGAT4C | c.*309T>G | 3'UTR (SNP) | VAF 21/53 reads (40%) | called by muse, mutect2, varscan2
- MUC15 | c.*983T>C | 3'UTR (SNP) | VAF 5/65 reads (8%) | called by muse, mutect2
- NLN | c.*5549G>C | 3'UTR (SNP) | VAF 8/154 reads (5%) | called by muse, mutect2
- NWD1 | c.*390T>A | 3'UTR (SNP) | VAF 19/121 reads (16%) | called by muse, mutect2, varscan2
- PCDHGA12 | c.*1577G>T | 3'UTR (SNP) | VAF 28/281 reads (10%) | called by muse, mutect2
- PIFO | c.*419G>A | 3'UTR (SNP) | VAF 7/68 reads (10%) | called by muse, mutect2, varscan2
- PNPLA3 | c.*973del | 3'UTR (DEL) | VAF 6/21 reads (29%) | called by mutect2, varscan2
- PPME1 | c.*1181C>A | 3'UTR (SNP) | VAF 25/90 reads (28%) | called by muse, mutect2, varscan2
- PTPRN2 | c.2344+5284G>A | Intron (SNP) | VAF 28/164 reads (17%) | catalogued as rs1250526200; called by muse, mutect2, varscan2
- PUM2 | c.*1711T>G | 3'UTR (SNP) | VAF 10/106 reads (9%) | called by muse, mutect2, varscan2
- RAB3B | c.*1326T>C | 3'UTR (SNP) | VAF 38/82 reads (46%) | called by muse, mutect2, varscan2
- RBM7 | c.*22T>G | 3'UTR (SNP) | VAF 48/336 reads (14%) | called by muse, mutect2, varscan2
- RCHY1 | c.-308C>T | 5'UTR (SNP) | VAF 16/172 reads (9%) | called by muse, mutect2
- RCOR1 | c.*3301C>G | 3'UTR (SNP) | VAF 51/126 reads (40%) | catalogued as COSV51771092; called by muse, varscan2
- RPS17 | c.*396T>A | 3'UTR (SNP) | VAF 21/715 reads (3%) | called by muse, mutect2
- S1PR2 | c.-43+784C>T | Intron (SNP) | VAF 39/96 reads (41%) | catalogued as rs538224926, COSV73912640, COSV73912837; called by muse, mutect2, varscan2
- SDC2 | c.-406_-385del | 5'UTR (DEL) | VAF 14/172 reads (8%) | called by mutect2, pindel
- SHBG | c.111+45C>G | Intron (SNP) | VAF 12/111 reads (11%) | called by muse, mutect2, varscan2
- SLC12A7 | c.1454+110A>C | Intron (SNP) | VAF 7/84 reads (8%) | called by muse, mutect2
- STK32B | c.*442G>C | 3'UTR (SNP) | VAF 63/116 reads (54%) | called by muse, mutect2, varscan2
- STX4 | chr16:31033494 A>T | 5'Flank (SNP) | VAF 138/274 reads (50%) | called by muse, mutect2, varscan2
- SYNCRIP | chr6:85610286 G>C | 3'Flank (SNP) | VAF 5/97 reads (5%) | called by muse, mutect2
- TECPR2 | c.*3724C>T | 3'UTR (SNP) | VAF 92/381 reads (24%) | called by muse, mutect2, varscan2
- TEF | c.*1495G>C | 3'UTR (SNP) | VAF 20/152 reads (13%) | catalogued as COSV99841794; called by muse, mutect2, varscan2
- TET2 | c.*257T>C | 3'UTR (SNP) | VAF 16/52 reads (31%) | called by muse, mutect2, varscan2
- TM9SF4 | c.*1345G>A | 3'UTR (SNP) | VAF 12/301 reads (4%) | called by muse, mutect2
- TSPAN33 | c.*704G>A | 3'UTR (SNP) | VAF 134/297 reads (45%) | called by muse, varscan2
- TTC39A | c.1162-1430C>T | Intron (SNP) | VAF 12/444 reads (3%) | called by muse, mutect2
- UBE2W | c.*7749G>A | 3'UTR (SNP) | VAF 6/92 reads (7%) | called by muse, mutect2
- VGLL3 | c.*6952C>G | 3'UTR (SNP) | VAF 6/59 reads (10%) | called by muse, mutect2, varscan2
- WRAP53 | c.-1123_-1100del | 5'UTR (DEL) | VAF 12/36 reads (33%) | called by pindel, varscan2
- XIAP | c.*42T>C | 3'UTR (SNP) | VAF 40/226 reads (18%) | called by muse, mutect2, varscan2
- ZBTB11 | c.-189A>T | 5'UTR (SNP) | VAF 37/248 reads (15%) | called by muse, mutect2, varscan2
- ZDHHC17 | c.*60G>T | 3'UTR (SNP) | VAF 7/39 reads (18%) | called by muse, mutect2, varscan2
- ZFP41 | c.*450G>A | 3'UTR (SNP) | VAF 22/247 reads (9%) | catalogued as rs1282167339; called by muse, mutect2
- ZMYM5 | chr13:19864275 G>A | 5'Flank (SNP) | VAF 43/58 reads (74%) | called by muse, varscan2
- ZNF735 | c.-9C>T | 5'UTR (SNP) | VAF 16/228 reads (7%) | catalogued as rs533616944, COSV70034485; called by muse, mutect2
